Gene-level copy-number profile of tumor specimen ALCH-AE8H-TTP1-B from ALCHEMIST case ALCH-AE8H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.5 years (29,409 days).
Specimen ALCH-AE8H-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e163a24a-9572-45f7-83bd-2fd30a67600b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE8H-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,751 have no estimate.
https://portal.gdc.cancer.gov/files/b6a615e1-270a-433a-bb32-6907b48d3a8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 11,379; copy number 2: 41,275; copy number 3: 6,150; copy number 4: 30; copy number 5: 12.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,617,160–91,723,605, 5 genes (within-gene range 0–1): LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2.
- chr9:9,442,060–9,803,784, 2 genes (within-gene range 0–1): RN7SL5P, AL513422.1.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:991,151–1,000,926, 1 gene: AC009041.1.
- chr16:1,065,240–1,066,502, 1 gene (within-gene range 0–1): AC009041.2.
- chr16:33,802,764–33,810,767, 2 genes: IGHV3OR16-12, AC136428.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,573,946–121,580,524, 1 gene, copy number 5: LINC01691.
- chr7:149,053,961–149,054,173, 1 gene, copy number 5: COX6B1P1.
- chr11:48,512,273–48,908,946, 10 genes, copy number 5: OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5.

Autosomal genes at a single copy (total copy number 1): 8,842. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
